Surgical pathology report (de-identified scan), TCGA case TCGA-09-1665, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1665-01B (Primary Tumor).

[page 1 of 7]
Specimen(s) Received

A: Uterus +/- tubes/ovaries, neoplastic (fa)

H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1, H&E, First x 1,
H&E, First x 1, H&E, First x 1,
H&E, First x 1, H&E, First x 1, H&E, First x 1, Wilms' Tumor x 1, Cytokeratin 7 x 1, Cytokeratin
20 x 1, Carcinoembryonic antigen

B: Left pelvic lymph node

C: Myoma

H&E, First x 1

D: Right pelvic lymph node

H&E, First x 1, H&E, First x 1

E: Sigmoid colon

H&E, First x 1, H&E, First x 1

F: Omentum, resection for tumor

H&E, First x 1

Final Pathologic Diagnosis:

A. Uterus, tubes, ovaries, cervix, rectum, left ureter, resection:

- Ovary, left:

1. Papillary Serous Cystadenocarcinoma, moderately differentiated,
grade

II/III, FIGO stage IIIC, 14.0 cm in greatest diameter.

2. Papillary Serous Cystadenocarcinoma metastatic to one of two
regional
lymph nodes (1/2)

- Ovary, right: Sections of benign ovary, no evidence of carcinoma.

- Fallopian tube, right: Section of benign fallopian tube, no evidence of
carcinoma.

- Fallopian tube, left: Not identified.

- Uterine corpus

- Myometrium:

1. Papillary Serous Cystadenocarcinoma metastatic to posterior uterine
corpus

by direct extension from the ovary and by lympho-vascular invasion.

2. Leiomyomata, intramural.

- Endometrium: Benign atrophic endometrium, no evidence of
metastatic
carcinoma.

- Cervix: Sections of benign cervix, no evidence of carcinoma.

[page 2 of 7]
- [REDACTED]
- Rectum: Metastatic Papillary Serous Cystadenocarcinoma Mucosal and transmural; largest metastasis measures 3.0 cm in greatest diameter, distal and proximal margins are negative.
- Ureter, left: Sections of benign ureter, no evidence of carcinoma.
- B. Lymph nodes, left pelvic, excision: Papillary Serous Cystadenocarcinoma metastatic to one of six lymph nodes (1/6).
- C. Soft tissue, excision: Leiomyoma.
- D. Lymph nodes, right pelvic, excision: Papillary Serous Cystadenocarcinoma metastatic to one of three lymph nodes (1/3).
- E. Sigmoid donut, excision: Colonic mucosa, no evidence of metastatic carcinoma.
- F. Omentum, resection: Fibrofatty tissue, no evidence of metastatic carcinoma.

Note: Ovarian Tumor Synoptic Comment

1. Type of tumor: Papillary Serous Cystadenocarcinoma
2. Grade of tumor: II/III.
3. Location of tumor: Unilateral, left ovary.
4. Diameter of tumor: 14.0 cm.
5. Appearance of surface of ovary: Smooth.
6. Condition of capsule: Intact.
7. Appearance of cut surface: Multilocular cyst, solid and cystic, mainly cystic.
8. Color of solid areas: Tan.
9. Necrosis: Moderate to extensive.
10. Lymphatic/vascular invasion: Lymphatic and blood vessel invasion.
11. Sites of metastases in pelvis (list all): Colon (transmural), uterine myometrium, lymph nodes.
12. Pelvic lymph nodes: three of eleven contain metastatic tumor.
13. Sites of metastases in abdomen (list all): None.
14. Para-aortic lymph nodes: None sampled.
15. Peritoneal cytology: Negative. Cytology accession number: [REDACTED]
16. Other significant findings: Leiomyomata.
17. FIGO stage: IIIC.
18. TNM stage: pT3cN1Mx.

Immunohistochemical stains were performed on block A11, the tumor cells are negative for progesterone but do express estrogen receptors, they are also CK7 positive and CK20 negative, WT-1 strongly positive and m-CEA weakly positive. This immunohistochemical profile is consistent with an ovarian papillary serous adenocarcinoma.

[REDACTED] reviewed the case and concurs with the interpretation.

[page 3 of 7]
Intraoperative Consult Diagnosis

FS1 (A) Uterus, ovaries, rectum, cervix, excision: Infiltrating ovarian carcinoma associated with serous cyst, infiltrating into colon; defer classification of carcinoma to permanent section and immunohistochemistry. [REDACTED]

Clinical History

The patient is a [REDACTED] with a history of a pelvic mass, undergoing resection of rectum and total abdominal hysterectomy and bilateral salpingo-oophorectomy.

Gross Description

The specimen is received in six parts, each labeled with the patient's name and medical record number. Parts A and C are received fresh, and Parts B, D-F are received in formalin. Part A is received fresh from the O.R., for frozen section, additionally labeled "uterus, cervix, ovaries,"
Page 2 of 6

rectum, and left ureter - FS," and consists of a composite resection specimen including: uterus (5.5 cm from superior to inferior, 5.0 cm cornu to cornu, and 3.5 cm anterior to posterior), cervix (1.5cm x 1.0cm), ovaries and fallopian tube, a segment of descending colon and rectum (23.0cm in length x 3.0cm diameter) and an unattached segment of ureter (5.0cm in length x 0.3cm in diameter). Centered in the left adnexa is a 14.0 x 7.0 x 6.5 cm solid and cystic mass. The solid portion (8.5 x 6.6 x 4.0 cm) is soft, pink-tan with areas of apparent necrosis, and comprises approximately 40% of the mass. The cystic portion of the mass is composed of multiple smooth walled cystic spaces without excrescences. No residual ovary is identified in the mass. The solid portion infiltrates through the distal portion of the rectum with invasion through the rectal wall, ulceration of the mucosa, and penetration into the lumen. The proximal and distal margins of the colon/rectum are free of tumor. Tumor approaches to within 3.5cm from the distal margin (rectum) and to within 10 cm of the proximal margin (descending colon). The tumor contains a cauterized surface near its invasion into the rectum. The surgeon indicates the separate segment of left ureter was present adjacent to this cauterized area. Additionally, tumor infiltrates into the posterior wall of the uterus with invasion into but not through the myometrial wall. The uterine cavity overlying the area of tumor invasion appears grossly unremarkable. The tumor does not appear to involve any other structures grossly. Two lymph nodes are found between the ovarian mass and the rectum. Representative sections of the solid component of the mass and sections of tumor

[page 4 of 7]
infiltrating rectum are submitted for frozen section diagnosis #1 with the frozen remnants in cassettes A1-A3. Additionally, portions of the mass as well as uninvolved endomyometrium are submitted for research.

The uterus additionally shows multiple nodules, sub-mucosal and sub-serosal, with firm, white-tan cut surfaces showing a whorled appearance. These nodules range in size from 0.7 to 2.2cm in maximal diameter and do not appear to be associated with the adnexal mass. No areas of hemorrhage, necrosis, or cystic degeneration are identified in these nodules. The ectocervix (1.0 x 1.0 cm) has a smooth white-tan surface without focal lesions. The cervical os is fish-mouthed and measures 0.7 cm in greatest dimension. The endocervix has glistening tan-brown mucosa and appears grossly unremarkable. The endometrium is thin, tan-brown, and grossly appears atrophic. The right ovary is white-tan, measures 2.5 x 1.5 x 0.8 cm and shows no gross abnormalities. The right fallopian tube (4.5 cm length x 0.5 cm diameter) appears grossly unremarkable. The anatomic area of the left fallopian tube appears to consist entirely of infiltrating tumor and no residual fallopian tube is identified grossly. The separate portion of left ureter is unoriented, appears intact, and shows no evidence of involvement by tumor. Representative sections are submitted as follows:

- Cassettes A1-A3: Frozen section remnants.
- Cassette A4: Cervix, anterior and posterior.
- Cassette A5: Leiomyomata.
- Cassette A6: Endomyometrium.
- Cassette A7: Right ovary and right fallopian tube.
- Cassette A8: Two regional lymphnodes.
- Cassettes A9-A10: Cystic portion of mass.
- Cassettes A11-A12: Tumor near inked cyst wall.
- Cassettes A13-A14: Distal colon margin, en face.
- Cassettes A15-A16: Proximal colon margin, en face.
- Cassettes A17-A18: Tumor infiltrating uterus.
- Cassettes A19-A20: Bowel with tumor and cauterized area (inked) and cyst wall; inked margin in cassette A20.
- Cassettes A21-A22: Cauterized inked margin and bowel.
- Cassettes A23-A27: Representative sections of tumor under ovarian cyst.
- Cassette A28: Large bowel tumor and margin (cauterized).
- Cassettes A29-A30: Representative sections of large bowel tumor.
- Cassette A31: Small colonic tumor.
- Cassettes A32-A33: Extra colonic nodule.
- Cassettes A34-A35: Representative sections of uninvolved bowel.
- Cassette A36: Either end of left ureter.
- Cassettes A37-39: Colon with left ovary.
- Cassettes 40-42: Left ovary.

Part B is additionally labeled "2 - left pelvic lymph node," and consists of two

[page 5 of 7]
[REDACTED]

unoriented, rubbery, tan-brown, irregularly shaped tissue fragments, the larger measuring 3.0 x 1.5 x 1.0 cm and the smaller measuring 2.0 x 1.0 x 1.0 cm. The specimen appears to consist of candidate nodes with a small portion of

Page 3 of 6

attached adipose tissue. The largest node measures 2.0 cm in greatest dimension. The largest node is bisected and submitted in cassette B1. The remaining candidate nodes are submitted in cassette B2.

Part C is additionally labeled "1 - myoma," and consists of one unoriented, firm, white-tan, irregularly shaped tissue fragment measuring 4.5 x 4.0 x 2.5 cm and weighing 26.9 gm. The specimen is inked blue.

Cross sectioning reveals white-tan tissue in a whorled pattern, consistent with leiomyoma. No areas of hemorrhage, necrosis or cystic degeneration are identified. Three representative sections are submitted in cassette C1.

Part D is additionally labeled "4 - right pelvic lymph node," and consists of three unoriented, rubbery, tan-brown, irregularly shaped tissue fragments, the largest measuring 2.5 x 2.0 x 1.3 cm. The specimen measures 3.0 x 2.5 x 1.5 cm in aggregate. The largest fragment is bisected and submitted in cassette D1.

The two smaller fragments are submitted in cassette D2.

Part E is additionally labeled "6 - sigmoid donut," and consists of two unoriented donut fragments of colon, the larger measuring 2.5 x 1.5 x 1.0 cm and the smaller measuring 1.5 x 1.5 x 1.0 cm. Tissue is teased away from the staples, and sections of the larger fragment are submitted in cassette E1. Sections of the smaller fragment are submitted in cassette E1.

Part F is additionally labeled "5 - omentum," and consists of one unoriented soft, yellow-tan, irregularly shaped fragment of fatty and membranous tissue, measuring 9.0 x 4.0 x 1.0 cm. The specimen is thinly sliced, revealing no nodules or other focal lesions. The specimen consists of unremarkable-appearing fatty tissue. Three representative sections are submitted in cassette F1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics

[REDACTED] they have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high-complexity clinical testing.

[REDACTED]

[REDACTED]

[page 6 of 7]
[REDACTED]

Addenda

[REDACTED]

Addendum Comment

Result of Her-2/neu test: This carcinoma is negative for Her-2/neu oncoprotein overexpression.

An immunohistochemical assay was performed on block A11 using the CB11 monoclonal antibody to Her-2/neu oncoprotein. The staining intensity of this carcinoma was 0 on a scale of 0-3 with focal cytoplasmic staining only.

Carcinomas with staining intensity scores of 0 or 1 are considered *negative* for overexpression of Her-2/neu oncoprotein.

Those with a staining intensity score of 2 are considered *borderline*. We and others have observed that

many carcinomas with staining intensity scores of 2 do not show gene amplification. All carcinomas with

staining intensity scores of 2 are therefore submitted for FISH testing. The results of the FISH test are

issued directly from the molecular cytogenetics laboratory.

Carcinomas with staining intensity scores of 3 are considered *positive* for overexpression of Her-2/neu

oncoprotein. Tumors in this category show an excellent correlation between the results of

Page 4 of 6

immunohistochemical and FISH testing, and almost always show gene amplification. The immunoperoxidase stain(s) reported above were developed and their performance characteristics

[REDACTED] They have not been cleared or approved by the U. S. Food and Drug Administration. The

FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not

be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of

[REDACTED] as qualified to perform high-complexity clinical testing.

Other Specimens

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

[page 7 of 7]
[REDACTED]

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation

[REDACTED]

[REDACTED]

Specimen(s) Received: Peritoneal Washing

Final Diagnosis

Peritoneal Washing

BENIGN

[REDACTED]

[REDACTED]

Specimen(s) Received: Vaginal/Cervical, Thin Prep

Final Diagnosis

Vaginal/Cervical, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

Transformation zone components are present.

[REDACTED]

Source: NCI Genomic Data Commons file fe1a529f-2ff7-4e7c-9cfe-d438ea380c9a (TCGA-09-1665.0E311879-9B25-453D-B41A-7CC3048BB05E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).